FM case AD11232 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/e4dfe873-61e8-4b2f-95a5-738a54b48c92

Female, 45.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
